Gene-level copy-number profile of tumor specimen TCGA-L5-A891-01A from TCGA case TCGA-L5-A891, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 51.8 years (18,925 days).
Specimen TCGA-L5-A891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.c35b5aef-4567-4fee-97f9-acdceb4b6c37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A891-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf766b48-39f2-49d6-a1a2-3cd825ab96bd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,342; copy number 2: 21,346; copy number 3: 22,873; copy number 4: 10,982; copy number 5: 2,374; copy number 6: 354; copy number 7: 112; copy number 8: 268; copy number 10: 42; copy number 11: 26; copy number 12: 33; copy number 13: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A891-01A-11D-A36I-01): tumor purity 0.87, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 541 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,695,874–169,396,540, 14 genes, copy number 8 (within-gene range 3–8): AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1.
- chr1:205,657,851–206,177,246, 21 genes, copy number 7: SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2.
- chr3:40,970,541–41,260,096, 4 genes, copy number 7: AC099541.1, AC009743.1, MRPS31P1, CTNNB1.
- chr6:73,461,578–73,509,236, 1 gene, copy number 7 (within-gene range 4–7): MTO1.
- chr6:73,487,590–73,696,131, 7 genes, copy number 7: RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1.
- chr6:134,960,378–135,103,056, 1 gene, copy number 12 (within-gene range 5–12): HBS1L.
- chr6:135,055,033–135,497,765, 9 genes, copy number 12: AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA.
- chr8:33,370,824–35,093,509, 25 genes, copy number 7 (within-gene range 2–7): FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr8:37,421,341–37,779,768, 14 genes, copy number 10 (within-gene range 6–10): LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP.
- chr11:69,809,968–70,436,584, 22 genes, copy number 7: FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 7: AP001271.1.
- chr19:20,122,569–20,321,305, 12 genes, copy number 12 (within-gene range 3–12): AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1.
- chr19:29,002,319–29,015,160, 1 gene, copy number 7 (within-gene range 2–7): LINC01532.
- chr19:30,907,199–30,957,192, 2 genes, copy number 7: LINC01834, AC020897.1.
- chr19:33,906,352–33,927,625, 2 genes, copy number 7: AC008556.1, RN7SL150P.
- chr19:36,850,361–36,998,700, 5 genes, copy number 7: ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568.
- chr20:41,402,083–45,515,622, 99 genes, copy number 10–13 (within-gene range 6–13) (broad region; genes not listed).
- chr20:47,950,797–62,447,677, 280 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr22:37,367,960–37,427,479, 1 gene, copy number 7 (within-gene range 3–7): ELFN2.
- chr22:37,469,063–37,849,327, 20 genes, copy number 7 (within-gene range 5–7): MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0, GCAT, GALR3, ANKRD54.

Autosomal genes at a single copy (total copy number 1): 1,342. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
